Somatic mutation profile of tumor specimen 0DIDTO from CCDI case PBBVKV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.2 years (2,620 days).
Specimen 0DIDTO: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1acef58-5e4b-4903-9460-f3d4f0e21eec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIDS3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/74e4c158-c553-4a93-9720-ff963daf65ce

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTN6 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 140/580 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs147761774; called by muse, mutect2, varscan2
- CSMD2 | c.10082C>T p.S3361L | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as rs750437715, COSV53885364; called by muse, mutect2, varscan2
- FAM83H | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 18/588 reads (3%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1554623470, COSV101187102; called by muse, mutect2
- GATA3 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 56/219 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs991194737, COSV60520957; called by muse, mutect2, varscan2
- LIPC | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 170/376 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs545537175, COSV100134429; called by muse, mutect2, varscan2
- MINPP1 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 127/361 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.071); catalogued as rs752550671; called by muse, mutect2, varscan2
- PERM1 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.017); catalogued as rs982888289; called by muse, mutect2, varscan2
- PPP1R16B | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 21/344 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs768049487, COSV55381287; called by muse, mutect2
- PPP4R2 | c.1160A>G p.N387S | Missense Mutation (SNP) | VAF 81/439 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1166452667; called by muse, mutect2, varscan2
- REV1 | c.1784G>A p.R595H | Missense Mutation (SNP) | VAF 145/561 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766174901; called by muse, mutect2, varscan2
- BTNL8 | c.612A>G p.I204M | Missense Mutation (SNP) | VAF 56/756 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- KLHL10 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- MGAT4D | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 141/650 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NPHS1 | c.1330C>T p.L444= | Silent (SNP) | VAF 89/334 reads (27%) | called by muse, mutect2, varscan2
- OR5D18 | c.426C>T p.C142= | Silent (SNP) | VAF 35/666 reads (5%) | catalogued as rs748193440, COSV61737568; called by muse, mutect2
- SND1 | c.1140G>T p.G380= | Silent (SNP) | VAF 64/410 reads (16%) | called by mutect2, varscan2
- AP4M1 | c.*1402C>T | 3'UTR (SNP) | VAF 15/98 reads (15%) | called by muse, mutect2, varscan2
